CCDI case PBCIAP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Small intestine.
https://portal.gdc.cancer.gov/cases/9c4129bc-17b4-4577-abed-a1a81eab3b5a

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Myofibroblastic tumor, NOS: ICD-O-3 morphology code: 8825/1; Tissue or organ of origin: Small intestine, NOS; Age at diagnosis: 13.2 years (4,804 days).

Biospecimens (3 samples)
- Sample 0DSHSX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSHT8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSHTF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
